Somatic mutation profile of tumor specimen C3L-01637-03 (aliquot CPT0086190010_1) from CPTAC case C3L-01637, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 78.6 years (28,706 days).
Specimen C3L-01637-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba56c1ba-4907-425f-a1bf-120dcb5f0571.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01637-31 (Blood Derived Normal), aliquot CPT0087390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1461909-23b3-49b7-8322-9ea666c6056f

The open-access MAF lists 52 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Intron 4, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 52/434 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 71/431 reads (16%) | catalogued as rs1555687378, COSV61684132; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 92/484 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS14 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775055593, COSV100941798; called by muse, mutect2, varscan2
- CCAR2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs376168583, COSV51514431; called by muse, mutect2, varscan2
- DTNBP1 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 42/1180 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59038226; called by muse, mutect2
- EMC1 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs558157154; called by muse, mutect2, varscan2
- HNRNPM | c.345T>G p.A115= | Splice Region (SNP) | VAF 22/392 reads (6%) | catalogued as COSV57695210; called by muse, mutect2
- HUNK | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.132); catalogued as rs367545209, COSV54224467, COSV54229031; called by muse, mutect2, varscan2
- IGFBP7 | c.237dup p.Y80Vfs*18 | Frame Shift Ins (INS) | VAF 39/335 reads (12%) | catalogued as rs969745457; called by mutect2, pindel, varscan2
- MORC1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 42/417 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV51730439; called by muse, mutect2, varscan2
- MTNR1B | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 21/249 reads (8%) | catalogued as rs551192907; called by muse, mutect2
- NAA11 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 84/633 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.218); catalogued as rs772384949; called by muse, mutect2, varscan2
- PPP1R16B | c.1427G>A p.S476N | Missense Mutation (SNP) | VAF 102/1018 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100239676; called by muse, mutect2, varscan2
- RIMS1 | c.4880A>G p.Y1627C | Missense Mutation (SNP) | VAF 75/431 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410122886; called by muse, mutect2, varscan2
- SIRPB1 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 199/1192 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs755452898; called by muse, mutect2, varscan2
- SMARCD1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs1442501952, COSV67411587; called by muse, mutect2, varscan2
- STK33 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV59397572; called by mutect2, varscan2
- TTN | c.6853G>T p.E2285* (on ENST00000591111; = p.E2239* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 58/483 reads (12%) | catalogued as COSV60168593; called by muse, mutect2, varscan2
- TTN | c.2506G>A p.G836S (on ENST00000591111; = p.G790S on NM_003319.4) | Missense Mutation (SNP) | VAF 67/546 reads (12%) | PolyPhen probably damaging (0.962); catalogued as rs751157908, COSV59988553, COSV60007599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC80 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.187); catalogued as rs768146438; called by muse, mutect2, varscan2
- ZNF569 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs532445392, COSV57595140; called by muse, mutect2, varscan2
- C11orf94 | c.55del p.L19Sfs*15 | Frame Shift Del (DEL) | VAF 67/509 reads (13%) | called by mutect2, pindel, varscan2
- CAPN15 | c.440_453del p.W147Lfs*29 | Frame Shift Del (DEL) | VAF 48/301 reads (16%) | called by mutect2, pindel, varscan2
- CDC6 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 65/477 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CFAP57 | c.904G>C p.G302R | Missense Mutation (SNP) | VAF 147/1010 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DCUN1D5 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX15 | c.841A>G p.R281G | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2
- GDI2 | c.777del p.I259Mfs*7 | Frame Shift Del (DEL) | VAF 42/365 reads (12%) | called by mutect2, pindel, varscan2
- GRAMD4 | c.1634C>G p.P545R | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMTOR1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 45/386 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MALRD1 | c.3881A>T p.D1294V | Missense Mutation (SNP) | VAF 58/365 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR10A2 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 108/806 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by mutect2, varscan2
- PI4KA | c.2107A>C p.R703= | Splice Region (SNP) | VAF 88/491 reads (18%) | called by muse, mutect2, varscan2
- STOML1 | c.298dup p.Q100Pfs*13 | Frame Shift Ins (INS) | VAF 26/137 reads (19%) | called by mutect2, pindel, varscan2
- TRIM42 | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 68/489 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ZNF208 | c.637T>A p.S213T | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ATP10D | c.2736G>A p.A912= | Silent (SNP) | VAF 32/280 reads (11%) | catalogued as rs201043225, COSV56707418; called by muse, mutect2, varscan2
- ATP1A3 | c.750C>T p.T250= (on ENST00000545399 / NM_001256214.2; = p.T237= on NM_152296.5) | Silent (SNP) | VAF 141/1085 reads (13%) | called by muse, mutect2, varscan2
- BCAM | c.540C>G p.A180= | Silent (SNP) | VAF 66/587 reads (11%) | called by muse, mutect2, varscan2
- CACNA1H | c.1512G>A p.Q504= | Silent (SNP) | VAF 73/424 reads (17%) | called by muse, mutect2, varscan2
- CPB1 | c.831A>C p.A277= | Silent (SNP) | VAF 99/700 reads (14%) | called by muse, mutect2, varscan2
- KCNS3 | c.558T>C p.L186= | Silent (SNP) | VAF 69/450 reads (15%) | called by muse, mutect2, varscan2
- PARVA | c.384C>T p.V128= | Silent (SNP) | VAF 52/948 reads (5%) | called by muse, mutect2
- SPATC1 | c.912G>A p.S304= | Silent (SNP) | VAF 57/414 reads (14%) | catalogued as rs782610725; called by muse, mutect2, varscan2
- ZNF16 | c.1443C>A p.I481= | Silent (SNP) | VAF 65/509 reads (13%) | called by muse, mutect2, varscan2
- CPNE2 | c.927+982C>T | Intron (SNP) | VAF 6/129 reads (5%) | catalogued as rs1033022089; called by muse, mutect2
- DNM2 | c.*14C>T | 3'UTR (SNP) | VAF 25/188 reads (13%) | catalogued as rs369529119; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851316 T>A | 5'Flank (SNP) | VAF 32/870 reads (4%) | called by muse, mutect2
- RANBP2 | c.1632-10T>A | Intron (SNP) | VAF 131/863 reads (15%) | called by muse, mutect2, varscan2
- TBX2 | c.1052-215G>T | Intron (SNP) | VAF 71/467 reads (15%) | called by muse, mutect2, varscan2
- UBAC2 | c.31+503T>C | Intron (SNP) | VAF 58/291 reads (20%) | called by muse, mutect2, varscan2
